Somatic mutation profile of tumor specimen TARGET-10-PARBBV-09A (aliquot TARGET-10-PARBBV-09A-01D) from TARGET case TARGET-10-PARBBV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,220 days).
Specimen TARGET-10-PARBBV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 430ef217-d2d7-4b08-b021-705072f79d06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBBV-10A (Blood Derived Normal), aliquot TARGET-10-PARBBV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1f1483c-a1c2-407c-856b-cc1e10115e80

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'Flank 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTDP1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs1260669909, COSV50003417, COSV99311077; called by muse, mutect2, varscan2
- OR4K13 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as rs998479002, COSV100237682; called by muse, mutect2, varscan2
- PLCL1 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRKCE | c.2171A>C p.E724A | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- AR | c.1885+3545del | Intron (DEL) | VAF 32/108 reads (30%) | called by mutect2, pindel, varscan2
- CLLU1 | chr12:92422753 G>A | 5'Flank (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2
